Gene-level copy-number profile of tumor specimen TCGA-VQ-A8DZ-01A from TCGA case TCGA-VQ-A8DZ, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Signet ring cell carcinoma; Tissue or organ of origin: Gastric antrum; AJCC pathologic stage: Stage IV; Tumor grade: G3; Age at diagnosis: 70.8 years (25,863 days).
Specimen TCGA-VQ-A8DZ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-STAD.40dbae55-e2d2-439f-843c-bea6eb4590d7.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-VQ-A8DZ-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/66fe2a85-d1a2-4505-837b-3dc029edbab1

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 52; copy number 1: 855; copy number 2: 14,804; copy number 3: 21,307; copy number 4: 15,937; copy number 5: 3,543; copy number 6: 1,287; copy number 7: 404; copy number 8: 339; copy number 9: 363; copy number 10: 275; copy number 11: 164; copy number 12: 55; copy number 13: 261; copy number 14: 91; copy number 15: 7; copy number 19: 7; copy number 22: 15; copy number 33: 14; copy number 37: 34.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-VQ-A8DZ-01A-11D-A363-01): tumor purity 0.6, ploidy 2.82, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 52 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:20,658,309–20,995,955, 1 gene (within-gene range 0–3): FOCAD.
- chr9:20,786,927–22,029,594, 47 genes (within-gene range 0–3): SNORA30B, HACD4, IFNNP1, IFNB1, IFNWP4, AL390882.1, IFNW1, Y_RNA, IFNA21, IFNWP15, IFNA4, IFNWP9, IFNA7, IFNA10, IFNWP18, IFNA16, IFNA17, IFNWP5, IFNA14, IFNA22P, IFNA5, IFNA20P, KLHL9, IFNA6, IFNA13, IFNA2, AL353732.1, IFNA11P, IFNA12P, IFNA8, AL353732.2, IFNWP2, IFNA1, MIR31HG, IFNWP19, IFNE, MIR31, SNORD39, H3P30, KHSRPP1, RN7SL151P, MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3.
- chr16:78,495,926–78,553,296, 4 genes: AC046158.1, AC046158.4, AC046158.2, AC046158.3.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 2,029 genes in 19 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:152,121,684–154,510,685, 35 genes, copy number 7–15 (within-gene range 6–15): SYNE1, SYNE1-AS1, AL049548.1, RNA5SP223, NANOGP11, MYCT1, HSPD1P16, VIP, LINC02840, TUBB4BP7, AL080276.1, FBXO5, AL080276.2, MTRF1L, RGS17, RNA5SP224, AL590867.1, AL590867.2, AL358134.1, RNA5SP225, MTCO2P31, AL603908.1, MTATP6P31, MTCO3P31, MTND3P20, MTND4LP20, MTND4P13, RNU6-896P, HMGB3P19, OPRM1, IPCEF1, AL357075.4, AL445220.1, CNKSR3, AL357075.2.
- chr6:155,380,511–155,655,026, 3 genes, copy number 8: AL031773.1, NOX3, RNU7-152P.
- chr8:73,651,289–76,683,308, 48 genes, copy number 7 (within-gene range 5–7): VENTXP6, AC027018.1, AC022826.2, UBE2W, AC022826.1, RN7SL760P, AC022868.1, GYG1P1, ELOC, TMEM70, RPS20P21, DSTNP3, LY96, RNU6-1300P, AC087672.2, RPS3AP32, RNU6-1197P, AC087627.1, AC087672.1, JPH1, GDAP1, AC103952.1, Y_RNA, MIR5681A, MIR5681B, MIR2052HG, PCBP2P2, AC115837.1, MIR2052, AC011632.1, AC026616.1, PI15, AC011632.2, CRISPLD1, AC100782.1, CASC9, LINC02886, HIGD1AP6, PKMP4, HNF4G, AC011029.1, RNU2-54P, AC067773.1, LINC01109, LINC01111, ZFHX4-AS1, AC013509.1, MRPL9P1.
- chr8:78,148,101–110,809,894, 533 genes, copy number 9–14 (within-gene range 2–14) (broad region; genes not listed).
- chr11:34,404,663–41,459,773, 61 genes, copy number 8–13 (within-gene range 6–13) (broad region; genes not listed).
- chr11:41,122,907–42,253,721, 11 genes, copy number 7–8: RNU6-365P, AC090138.1, LINC02741, AC021006.1, AC021006.2, LINC01499, AC023442.1, AC023442.3, AC023442.2, LINC02745, LINC02740.
- chr13:28,232,501–114,337,626, 1,138 genes, copy number 7–33 (broad region; genes not listed).
- chr17:26,981,694–27,352,828, 15 genes, copy number 22: AC069061.1, AC069061.2, PDLIM1P3, GTF2IP6, VN1R71P, TUFMP1, AC129926.2, AC129926.1, RPL34P31, RPS16P8, AC026254.1, MIR4522, WSB1, AC026254.2, SYPL1P2.
- chr17:38,996,323–39,864,312, 34 genes, copy number 37 (within-gene range 4–37): AC006441.2, AC006441.4, AC006441.5, LINC02079, LRRC37A11P, AC091178.1, RDM1P5, PLXDC1, AC091178.2, ARL5C, AC004408.2, AC004408.1, CACNB1, RPL19, STAC2, AC015910.1, FBXL20, AC005288.1, MED1, CDK12, RNU6-233P, AC009283.1, NEUROD2, AC087491.1, PPP1R1B, STARD3, TCAP, PNMT, PGAP3, ERBB2, MIR4728, MIEN1, GRB7, IKZF3.
- chr20:19,756,390–20,056,046, 5 genes, copy number 7: AL121761.1, RIN2, RPL12P12, NAA20, CRNKL1.
- chr20:20,094,401–20,095,684, 1 gene, copy number 7: AL035454.1.
- chr20:47,859,788–48,275,392, 13 genes, copy number 7: SRMP1, RNA5SP486, RNU7-92P, AL357558.2, AL357558.1, AL357558.3, LINC01522, LINC01523, AL139351.2, AL139351.3, AL139351.1, AL136102.1, AL121888.2.
- chr20:48,921,711–50,153,637, 34 genes, copy number 9 (within-gene range 5–9): ARFGEF2, SNAP23P1, CSE1L-AS1, CSE1L, STAU1, ARPC3P1, DDX27, ZNFX1, ZFAS1, AL049766.2, SNORD12C, AL049766.1, SNORD12B, AL049766.3, SNORD12, KCNB1, AL035685.1, PTGIS, B4GALT5, RN7SL197P, SNRPFP1, RNU6-919P, SLC9A8, AL162615.1, SPATA2, Y_RNA, Metazoa_SRP, RNF114, KRT18P4, RNU6-147P, SNAI1, TRERNA1, UBE2V1, PEDS1-UBE2V1.
- chr20:52,511,252–53,827,297, 21 genes, copy number 9: MRPS33P4, AL031674.1, AL161945.1, AL121902.1, RPL36P1, TSHZ2, RN7SKP184, AL391097.3, AL391097.1, AL391097.2, AL109930.1, AL354993.1, PPIAP10, AL354993.2, Y_RNA, AL157838.1, ZNF217, AC005808.1, RNU7-14P, AC005914.1, AC006076.1.
- chr20:57,266,797–58,004,648, 21 genes, copy number 9: AL122058.1, Y_RNA, MIR4325, RPL39P39, SPO11, RAE1, MTND1P9, MTRNR2L3, RBM38-AS1, RBM38, AL109955.1, HMGB1P1, CTCFL, PCK1, AL035541.1, ZBP1, PMEPA1, NKILA, AL162291.1, AL354984.1, LINC01742.
- chr20:58,228,940–58,981,169, 27 genes, copy number 9 (within-gene range 4–9): PPP4R1L, RAB22A, VAPB, APCDD1L, APCDD1L-DT, AL050327.1, LINC01711, STX16, STX16-NPEPL1, NPEPL1, AL139349.1, PIEZO1P2, AL132655.3, AL132655.2, MIR296, MIR298, GNAS-AS1, AL132655.1, GNAS, AL132655.7, AL132655.6, AL132655.4, AL132655.5, AL121917.1, AL121917.2, AL109840.2, AL109840.1.
- chr20:61,252,261–61,940,617, 1 gene, copy number 9 (within-gene range 6–9): CDH4.
- chr20:61,717,506–62,367,312, 17 genes, copy number 9 (within-gene range 5–9): AL162457.1, AL162457.2, TAF4, MIR1257, AL137077.1, MIR3195, AL137077.2, LSM14B, PSMA7, SS18L1, MTG2, HRH3, OSBPL2, ADRM1, AL354836.1, LAMA5, MIR4758.
- chr21:35,887,195–36,126,640, 11 genes, copy number 7: PPP1R2P2, LINC01436, RPL23AP3, SETD4, RIMKLBP1, SETD4-AS1, RNU6-992P, AP000688.1, CBR1, AP000688.3, AP000688.2.

Autosomal genes at a single copy (total copy number 1): 855. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
